CCDI case PBCJXM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f93385de-5fea-48e1-8575-79fff2c65568

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Schwannoma, NOS: ICD-O-3 morphology code: 9560/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.5 years (5,287 days).

Biospecimens (3 samples)
- Sample 0DTM9P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTM9W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTMA1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
